Somatic mutation profile of tumor specimen C3N-04113-03 (aliquot CPT0285640006) from CPTAC case C3N-04113, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 31.0 years (11,338 days).
Specimen C3N-04113-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2013a354-b36e-44b9-b6a9-04b06fe03fe2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-04113-31 (Blood Derived Normal), aliquot CPT0285650002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/302c4a54-7d3c-4408-93bd-1542cdf20a88

The open-access MAF lists 98 somatic variants for this specimen: 68 protein-altering or splice-affecting, 18 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 18, Frame Shift Del 6, Intron 5, Splice Site 4, Nonsense Mutation 3, RNA 3, In Frame Del 3, 5'UTR 2, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.3097C>T p.Q1033* | Nonsense Mutation (SNP) | VAF 92/140 reads (66%) | catalogued as rs1131691104, CM143358, COSV62222126; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.70G>C p.D24H | Missense Mutation (SNP) | VAF 32/263 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as rs786201995, CM110141, CM993669, COSV64288588, COSV64289716, COSV64295411; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RB1 | c.2520+3_2520+6del p.X840_splice | Splice Site (DEL) | VAF 15/44 reads (34%) | catalogued as rs1131690858; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.310C>T p.Q104* | Nonsense Mutation (SNP) | VAF 94/164 reads (57%) | hotspot (GDC flag); catalogued as rs1567555934, COSV52694629; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CCL26 | c.239G>T p.W80L | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs781876515, COSV104374631; called by muse, mutect2
- CD163L1 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 106/380 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as rs139153315; called by muse, mutect2, varscan2
- CDH9 | c.1760G>A p.R587H | Missense Mutation (SNP) | VAF 22/407 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as rs763497540, COSV50254621, COSV50464003; called by muse, mutect2
- CEP192 | c.1600-1G>A p.X534_splice | Splice Site (SNP) | VAF 101/217 reads (47%) | catalogued as COSV58063914; called by muse, mutect2, varscan2
- DDHD1 | c.1222A>G p.M408V (on ENST00000323669; = p.M605V on NM_030637.3) | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1358278519; called by muse, mutect2
- DNAH10 | c.677T>A p.V226D (on ENST00000409039; = p.V165D on NM_207437.3) | Missense Mutation (SNP) | VAF 13/295 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV68990317; called by muse, mutect2
- DNAH5 | c.7771G>T p.E2591* | Nonsense Mutation (SNP) | VAF 21/112 reads (19%) | catalogued as COSV54238623, COSV99448383; called by muse, mutect2, varscan2
- DNAJB13 | c.172+1G>A p.X58_splice | Splice Site (SNP) | VAF 22/141 reads (16%) | catalogued as COSV60268673; called by muse, mutect2, varscan2
- FLRT3 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1316194307, COSV53975772; called by muse, mutect2
- HINT2 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT tolerated (0.85); PolyPhen benign (0.058); catalogued as rs751219625, COSV52414128; called by muse, mutect2
- HIPK2 | c.3479C>T p.P1160L | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as COSV101301629; called by muse, mutect2, varscan2
- LOXHD1 | c.1825A>G p.I609V | Missense Mutation (SNP) | VAF 77/299 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.203); catalogued as rs1453952589; called by muse, mutect2, varscan2
- MAN1A2 | c.967_968del p.W323Gfs*7 | Frame Shift Del (DEL) | VAF 102/202 reads (50%) | catalogued as COSV62977458; called by mutect2, pindel, varscan2
- MYO3A | c.1170G>T p.K390N | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as rs771616016; called by muse, mutect2
- NPAP1 | c.266G>T p.G89V | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.06); catalogued as rs780245958, COSV100276224; called by muse, mutect2, varscan2
- OVCH1 | c.1114G>T p.V372F | Missense Mutation (SNP) | VAF 13/288 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.692); catalogued as COSV58959985; called by muse, mutect2
- PDE2A | c.1807T>C p.F603L | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.253); catalogued as COSV57808511; called by muse, mutect2
- RPN1 | c.1403C>T p.A468V | Missense Mutation (SNP) | VAF 82/214 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.113); catalogued as rs1181375835; called by mutect2, varscan2
- SH3TC2 | c.2604G>T p.E868D | Missense Mutation (SNP) | VAF 24/191 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.369); catalogued as COSV60467278; called by muse, mutect2, varscan2
- SMG1 | c.5557C>G p.P1853A | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs772066609; called by muse, mutect2, varscan2
- TMEM132C | c.2629G>A p.G877S | Missense Mutation (SNP) | VAF 62/180 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as rs1040291543; called by muse, mutect2, varscan2
- TRIM26 | c.1043C>T p.P348L | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs1383205581; called by muse, mutect2
- TRPM2 | c.1901G>A p.R634H | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.035); catalogued as rs368348703; called by muse, mutect2, varscan2
- TSPO | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 65/246 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.659); catalogued as rs1183984026; called by muse, mutect2, varscan2
- UBTFL1 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 31/275 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as rs769544073, COSV73297912; called by muse, mutect2, varscan2
- ZCWPW1 | c.588_590del p.K197del | In Frame Del (DEL) | VAF 106/235 reads (45%) | catalogued as rs771228931; called by pindel, varscan2
- ABI3BP | c.703T>C p.Y235H | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AFAP1L2 | c.2113+1G>T p.X705_splice | Splice Site (SNP) | VAF 8/60 reads (13%) | called by muse, varscan2
- ARSH | c.425G>A p.G142E | Missense Mutation (SNP) | VAF 26/284 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ASXL3 | c.4871_4874del p.H1624Rfs*10 | Frame Shift Del (DEL) | VAF 86/196 reads (44%) | called by pindel, varscan2
- BCLAF1 | c.2368G>C p.A790P | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.093); called by muse, varscan2
- BCLAF1 | c.2043G>C p.K681N | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- BEST4 | c.855C>G p.D285E | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CCDC85A | c.1145G>T p.G382V | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.051); called by muse, mutect2
- CCDC87 | c.170C>T p.S57L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CFAP46 | c.5688G>T p.Q1896H | Missense Mutation (SNP) | VAF 38/316 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CNGB1 | c.3437C>T p.A1146V | Missense Mutation (SNP) | VAF 51/426 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- CNRIP1 | c.9C>A p.D3E | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.003); called by muse, varscan2
- CXCL10 | c.41T>A p.L14Q | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- DAO | c.276C>G p.I92M | Missense Mutation (SNP) | VAF 66/358 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- DNM1 | c.791C>G p.S264C | Missense Mutation (SNP) | VAF 30/287 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- EPHA3 | c.2432G>T p.G811V | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EXD3 | c.1367C>T p.P456L | Missense Mutation (SNP) | VAF 37/205 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- FAM151A | c.1696G>C p.V566L | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.2); called by muse, mutect2
- GTF2F2 | c.742_743del p.S248* | Frame Shift Del (DEL) | VAF 30/108 reads (28%) | called by pindel, varscan2
- ISM1 | c.525C>A p.D175E | Missense Mutation (SNP) | VAF 280/426 reads (66%) | SIFT tolerated (0.88); PolyPhen benign (0.006); called by muse, varscan2
- KRTAP13-4 | c.160A>G p.T54A | Missense Mutation (SNP) | VAF 8/199 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.686); called by muse, mutect2
- LEF1 | c.709A>T p.T237S | Missense Mutation (SNP) | VAF 45/171 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MAD1L1 | c.2051A>C p.H684P | Missense Mutation (SNP) | VAF 23/362 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- MIGA2 | c.274_276del p.L93del | In Frame Del (DEL) | VAF 185/287 reads (64%) | called by mutect2, pindel, varscan2
- MMP12 | c.1307A>T p.K436I | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NEBL | c.1142A>G p.K381R | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NPAS4 | c.123C>A p.H41Q | Missense Mutation (SNP) | VAF 51/171 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- OR10Q1 | c.809G>C p.S270T | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- OR2AK2 | c.325G>A p.G109R | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- PEG3 | c.1829C>T p.P610L | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POC1B | c.1369G>C p.E457Q | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- PREP | c.1217G>T p.G406V (on ENST00000369110; = p.G472V on NM_002726.5) | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PSMC2 | c.530T>C p.V177A | Missense Mutation (SNP) | VAF 12/282 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2
- RAI1 | c.5686_5690del p.S1896Efs*6 | Frame Shift Del (DEL) | VAF 125/219 reads (57%) | called by mutect2, pindel, varscan2
- RNF150 | c.1199G>A p.S400N | Missense Mutation (SNP) | VAF 102/141 reads (72%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- THSD1 | c.641_642del p.Y214Cfs*21 | Frame Shift Del (DEL) | VAF 23/112 reads (21%) | called by mutect2, pindel, varscan2
- VCPIP1 | c.3439_3441del p.S1147del | In Frame Del (DEL) | VAF 40/138 reads (29%) | called by pindel, varscan2
- ZNF549 | c.1785_1788del p.Y596Kfs*40 (on ENST00000376233 / NM_001199295.2; = p.Y583Kfs*40 on NM_153263.2) | Frame Shift Del (DEL) | VAF 79/156 reads (51%) | called by mutect2, pindel, varscan2
- C4orf54 | c.2148C>A p.A716= | Silent (SNP) | VAF 38/147 reads (26%) | catalogued as COSV72766911; called by muse, mutect2, varscan2
- CFAP65 | c.762C>T p.P254= | Silent (SNP) | VAF 162/249 reads (65%) | catalogued as rs1231256569; called by muse, mutect2, varscan2
- CSPG4 | c.6181C>T p.L2061= | Silent (SNP) | VAF 24/434 reads (6%) | catalogued as rs1421034238; called by muse, mutect2
- ESPN | c.279C>T p.G93= | Silent (SNP) | VAF 173/672 reads (26%) | called by muse, mutect2, varscan2
- IGHMBP2 | c.2052G>A p.Q684= | Silent (SNP) | VAF 48/127 reads (38%) | called by muse, mutect2, varscan2
- KRT6A | c.1581C>T p.F527= | Silent (SNP) | VAF 64/918 reads (7%) | catalogued as rs1053722; called by muse, mutect2
- NOD1 | c.1005C>A p.G335= | Silent (SNP) | VAF 15/542 reads (3%) | called by muse, mutect2
- OR2A5 | c.360C>T p.Y120= | Silent (SNP) | VAF 16/264 reads (6%) | catalogued as rs769204145, COSV101278852; called by muse, mutect2
- POTEE | c.2379G>A p.E793= | Silent (SNP) | VAF 427/750 reads (57%) | called by muse, varscan2
- PXMP2 | c.435G>A p.R145= | Silent (SNP) | VAF 116/388 reads (30%) | called by muse, mutect2, varscan2
- RAPGEF3 | c.1878C>T p.L626= (on ENST00000389212; = p.L584= on NM_006105.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/359 reads (5%) | called by muse, mutect2
- SHANK2 | c.858C>T p.H286= | Silent (SNP) | VAF 24/495 reads (5%) | catalogued as rs782463740; called by muse, mutect2
- SLC10A5 | c.1146C>T p.A382= | Silent (SNP) | VAF 96/135 reads (71%) | catalogued as rs1268052622; called by muse, mutect2, varscan2
- SLC22A24 | c.864C>T p.S288= | Silent (SNP) | VAF 16/186 reads (9%) | catalogued as rs758802285; called by muse, mutect2
- SLC4A9 | c.1353A>G p.T451= (on ENST00000507527 / NM_001258428.2; = p.T427= on NM_031467.3) | Silent (SNP) | VAF 39/61 reads (64%) | called by muse, mutect2, varscan2
- STAU1 | c.519A>G p.G173= (on ENST00000371856 / NM_001319135.1; = p.G92= on NM_004602.3) | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as rs1373597280; called by muse, mutect2, varscan2
- XIRP1 | c.2148C>T p.I716= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as rs752561906, COSV61136762; called by muse, mutect2, varscan2
- ZNF227 | c.1596C>T p.S532= | Silent (SNP) | VAF 145/239 reads (61%) | catalogued as rs774679433; called by muse, mutect2, varscan2
- AGXT2 | c.1188+48_1188+51del | Intron (DEL) | VAF 189/281 reads (67%) | called by mutect2, pindel, varscan2
- AL590867.2 | n.53G>A | RNA (SNP) | VAF 94/454 reads (21%) | catalogued as rs776253514; called by muse, mutect2, varscan2
- ATXN2 | c.731+992_731+995del | Intron (DEL) | VAF 33/178 reads (19%) | called by mutect2, pindel, varscan2
- CHCHD3 | c.525-19016_525-19015del | Intron (DEL) | VAF 30/131 reads (23%) | called by mutect2, pindel, varscan2
- DCAF17 | c.-62C>A | 5'UTR (SNP) | VAF 91/256 reads (36%) | catalogued as rs1256152679; called by muse, mutect2, varscan2
- GGA2 | c.*2233_*2236del | 3'UTR (DEL) | VAF 89/140 reads (64%) | called by mutect2, pindel, varscan2
- MIR518A1 | n.38G>T | RNA (SNP) | VAF 18/156 reads (12%) | catalogued as rs763048695; called by muse, mutect2, varscan2
- MMP13 | c.*19T>G | 3'UTR (SNP) | VAF 27/201 reads (13%) | called by muse, mutect2, varscan2
- NRP1 | c.1759+1292G>A | Intron (SNP) | VAF 93/182 reads (51%) | called by muse, mutect2, varscan2
- PSPH | c.-9C>T | 5'UTR (SNP) | VAF 104/764 reads (14%) | catalogued as COSV99304700; called by muse, varscan2
- PTPN6 | c.1362-47C>T | Intron (SNP) | VAF 97/274 reads (35%) | catalogued as rs782173800; called by muse, mutect2, varscan2
- UBTFL2 | n.778C>T | RNA (SNP) | VAF 43/729 reads (6%) | catalogued as rs767760358; called by muse, mutect2
